Surgical pathology report (de-identified scan), TCGA case TCGA-44-7659, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-7659-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Final Surgical Pathology Report

Procedure: [REDACTED]

Diagnosis

A. Lung, left upper lobe, lobectomy:
Invasive moderately differentiated adenocarcinoma.
Bronchial and vascular margins of resection free of tumor.
11 hilar lymph nodes negative for metastatic carcinoma (0/11).
Lymphovascular invasion by tumor is present.

B. Lymph node, level V, resection:
Negative for metastatic carcinoma.

C. Lymph node, level II, resection:
Negative for metastatic carcinoma.

D. Lymph node, level VII, resection:
Negative for metastatic carcinoma.

E. Lymph node, level VI, resection:
Negative for metastatic carcinoma.

Note: Many of the sampled lymph nodes also contained old hyalinized granulomas.

Microscopic Description:

Histologic type: Adenocarcinoma.
Histologic grade: Moderately differentiated.
Primary tumor (pT): Tumor measures 2.9 cm maximally and is confined to the lung (pT1b).
Margins of resection: Negative.
Direct extension of tumor: Absent.
Venous (large vessel) invasion: Negative.
Arterial (large vessel) invasion: Negative.
Lymphatic (small vessel) invasion: Positive.
Regional lymph nodes (pN): All hilar lymph nodes and mediastinal lymph nodes are negative for metastatic carcinoma (pN0).
Distant metastasis (pM): pMx.

Specimen

A. Left upper lobe
B. Level V
C. level XI
D. level VII
E. Level VI

Clinical Information

Lung nodule

Gross Description

A. Received fresh subsequently fixed in formalin labeled "left upper lobe" is a lobe of lung which is heavily stapled and is 22.0 x 11.0 x 4.5 cm partially covered with a violaceous pink-tan smooth glistening pleura showing diffuse stippling present. Specimen shows a 2.9 x 2.9 x 2.5 cm gray-tan tumor which comes within 0.3 cm of the pleura. There is

[page 2 of 2]
a the pleura in this area is inked blue. There is a stapled margin in this area which is inked black. The tumor mass comes within 0.2 cm of the surgical margin (inked black). The remainder of the pleura is pink-tan and fleshy showing diffuse black stippling present. The tumor comes within 5.5 cm of the hilar my margin. Possible hilar lymph nodes which are black and are grossly identified. Rep. sections of the specimen are submitted as follows; 1-Rep. section of tumor to surgical margin and pleura, 2 through 3-representative section of tumor to pleura, 4-Rep. section of tumor to normal, 5-representative section of normal near apex, 6 - vascular and bronchial margins, 7 through 9 - possible hilar nodes. RS 9

B. Received fresh, subsequently fixed in formalin labeled "level V" is a 2.2 x 1.0 x 0.6 cm gray-pink irregular soft tissue fragment which is bisected to show black cut surface. Specimen is entirely submitted in one cassette. AS1

C. Received fresh, subsequently fixed in formalin labeled "level XI" are 2 pink red irregular soft tissue fragments which show black discoloration. These are 0.9 cm and 0.6 cm in greatest dimension. Vessels and are entirely submitted in one cassette. AS1.

D. Received fresh and subsequently fixed in formalin labeled level VII and a 1.4 x 0.4 x 0.3 cm black red irregular soft tissue fragment which is entirely submitted in one cassette. AS1.

E. Received fresh and subsequently fixed in formalin labeled "level VI" are multiple gray-pink irregular soft tissue fragments which have an aggregate measurement of 1.5 x 0.6 x 0.3 cm. The specimen are entirely submitted in one cassette. AS1.

Source: NCI Genomic Data Commons file bd04036e-989b-47ff-a24e-483700371111 (TCGA-44-7659.CA4281D7-0CD7-4EBC-8050-9DD81FBBEFBC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).